Somatic mutation profile of tumor specimen TCGA-E1-A7YH-01A (aliquot TCGA-E1-A7YH-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YH, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 47.8 years (17,465 days).
Specimen TCGA-E1-A7YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e6af687-fad0-4ba9-9420-5333f3b14055.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YH-10A (Blood Derived Normal), aliquot TCGA-E1-A7YH-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726178a2-e8de-4545-a28a-2b0585e989f1

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 21/32 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGAP2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs762323867, COSV100096346; called by muse, mutect2, varscan2
- ATRX | c.5135G>A p.G1712D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100970771; called by muse, mutect2, varscan2
- CMTM3 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs777705777, COSV58063311; called by muse, mutect2
- CYLC1 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as rs1300725278, COSV100254619; called by muse, mutect2, varscan2
- CYLC1 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100254624; called by muse, mutect2, varscan2
- DCAF8L1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV101491460; called by muse, mutect2, varscan2
- DTX1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs375934553, COSV99921419; called by muse, mutect2, varscan2
- HTR1D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757946711, COSV58447419; called by muse, mutect2, varscan2
- MACF1 | c.11513A>T p.D3838V (on ENST00000372915; = p.D1771V on NM_012090.5) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99244336; called by muse, mutect2
- MEST | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99784245; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- SEPTIN6 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595596; called by muse, mutect2, varscan2
- SLC9C2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs750156727, COSV62944020; called by muse, mutect2, varscan2
- TET1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV101018233, COSV65388687; called by muse, mutect2, varscan2
- TRMT2B | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100105363; called by muse, mutect2
- UGT8 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs201002468, COSV100179194; called by muse, mutect2, varscan2
- ZCCHC2 | c.2834C>T p.P945L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs774947135, COSV99502423; called by muse, mutect2, varscan2
- TMOD2 | c.242_245del p.K81Tfs*24 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- ARSD | c.546C>T p.N182= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV54198539; called by muse, mutect2, varscan2
- CA8 | c.870G>A p.Q290= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100526898; called by muse, mutect2, varscan2
- COX5B | c.315G>A p.L105= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99300274; called by muse, mutect2
- GNAT1 | c.336G>A p.E112= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1328717185, COSV99137373; called by muse, mutect2, varscan2
- TBX4 | c.1413T>C p.F471= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99540257; called by muse, mutect2, varscan2
- ZSCAN21 | c.1017A>G p.K339= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99460932; called by muse, mutect2, varscan2
